Somatic mutation profile of tumor specimen TARGET-40-0A4I4A-01A (aliquot TARGET-40-0A4I4A-01A-01D) from TARGET case TARGET-40-0A4I4A, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 21.2 years (7,748 days).
Specimen TARGET-40-0A4I4A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d76e810e-4b23-4532-ba2b-39ead0bb76db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I4A-10A (Blood Derived Normal), aliquot TARGET-40-0A4I4A-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60e9712c-4a39-4692-9dbc-6962a421b55d

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 2, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LILRB3 | c.297C>A p.H99Q | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1391484659; called by muse, varscan2
- MRE11 | c.851T>C p.V284A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- NPC1L1 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.245); called by muse, mutect2
- OR12D1 | c.748T>C p.S250P | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- PRAMEF6 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 30/738 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.924); called by muse, mutect2
- PSG7 | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- SEL1L3 | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.811); called by muse, mutect2
- SLC2A11 | c.282-6C>T | Splice Region (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- ASTN1 | c.630C>T p.G210= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV56064658; called by muse, mutect2, varscan2
- TBX4 | c.327C>T p.P109= | Silent (SNP) | VAF 13/169 reads (8%) | catalogued as rs749751811; called by muse, mutect2
- CIC | c.4328-10C>T | Intron (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- GNB1L | c.733-3885G>C | Intron (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- TBX1 | chr22:19782938 C>T | 3'Flank (SNP) | VAF 37/284 reads (13%) | called by muse, mutect2, varscan2
